Gene-level copy-number profile of tumor specimen TCGA-GU-AATP-01A from TCGA case TCGA-GU-AATP, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 74.1 years (27,049 days).
Specimen TCGA-GU-AATP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.7c160183-afe7-4ab6-9284-47c8238a804c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GU-AATP-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 833 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/494d12c7-43c7-4482-bad8-74058d398335

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 1,582; copy number 2: 22,235; copy number 3: 30,066; copy number 4: 4,652; copy number 5: 570; copy number 6: 132; copy number 7: 47; copy number 8: 237; copy number 9: 27; copy number 11: 60; copy number 13: 108; copy number 17: 35; copy number 18: 14; copy number 19: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GU-AATP-01A-11D-A390-01): tumor purity 0.65, ploidy 2.83, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 542 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:39,491,636–40,771,603, 60 genes, copy number 11: BMP8A, OXCT2P1, PPIEL, PABPC4, PABPC4-AS1, SNORA55, HEYL, AL035404.2, NT5C1A, HPCAL4, PPIE, AL035404.1, RNU7-121P, BMP8B, OXCT2, BMP8B-AS1, AL033527.2, AL033527.1, AL033527.3, LINC02811, TRIT1, Y_RNA, MYCL, MYCL-AS1, Y_RNA, MFSD2A, AL663070.1, CAP1, PPT1, OAZ1P1, RLF, RNU6-1237P, TMCO2, AL050341.2, ZMPSTE24, AL050341.1, COL9A2, AL031985.2, SMAP2, AL031985.1, AL031985.4, ZFP69B, AL031985.3, AL603839.4, ZFP69, AL603839.3, EXO5, AL603839.1, AL603839.2, ZNF684, AL356379.2, AL356379.1, GTF2F2P2, RIMS3, AL031289.2, AL031289.1, NFYC-AS1, NFYC, MIR30E, MIR30C1.
- chr1:107,140,007–107,965,180, 3 genes, copy number 7 (within-gene range 2–7): NTNG1, NDUFA4P1, VAV3.
- chr3:8,775,402–10,285,796, 54 genes, copy number 8–18 (within-gene range 3–18): RAD18, AC034186.2, AC034186.1, SRGAP3, SRGAP3-AS1, AC037193.1, SRGAP3-AS2, SRGAP3-AS3, SRGAP3-AS4, AC026191.1, PGAM1P4, THUMPD3-AS1, THUMPD3, SETD5, LHFPL4, DUSP5P2, MTMR14, AC022382.2, CPNE9, BRPF1, OGG1, CAMK1, TADA3, ARPC4, ARPC4-TTLL3, TTLL3, AC022382.1, RPUSD3, CIDEC, JAGN1, IL17RE, IL17RC, RNU6-882P, AC018809.3, CRELD1, AC018809.1, PRRT3, PRRT3-AS1, AC018809.2, EMC3, EMC3-AS1, CYCSP10, AC022007.1, CIDECP1, FANCD2, RNU6-670P, CYCSP11, FANCD2OS, BRK1, VHL, AC034193.1, IRAK2, TATDN2, AC022384.1.
- chr3:11,952,788–14,201,122, 45 genes, copy number 8: RN7SL147P, SYN2, ACTG1P12, TIMP4, MTCO1P5, GSTM5P1, PPARG, AC091492.1, TSEN2, RNA5SP123, RNU6-377P, MKRN2OS, MKRN2, Metazoa_SRP, RAF1, CRIP1P1, TMEM40, KRT18P17, CAND2, AC034198.2, RPL32, SNORA7A, AC034198.1, LINC02022, IQSEC1, AC069271.1, NUP210, AC027124.2, AC027124.1, HDAC11-AS1, HDAC11, FBLN2, LINC00620, WNT7A, VN1R20P, FGD5P1, TPRXL, AC090004.2, VN1R21P, CHCHD4, TMEM43, AC090004.1, XPC-AS1, XPC, LSM3.
- chr7:63,011,463–64,150,721, 77 genes, copy number 8–17 (broad region; genes not listed).
- chr7:98,106,862–98,215,457, 2 genes, copy number 8: LMTK2, BHLHA15.
- chr7:98,794,718–100,642,779, 105 genes, copy number 8–13 (broad region; genes not listed).
- chr13:73,191,528–73,227,260, 2 genes, copy number 7: RNU4-10P, RNY1P8.
- chr17:36,486,629–37,940,790, 42 genes, copy number 7: ZNHIT3, RNA5SP439, MYO19, PIGW, GGNBP2, AC243732.1, DHRS11, MRM1, AC243830.2, AC243830.3, AC243830.1, LHX1-DT, LHX1, AC243773.1, AATF, AC243773.2, AC244093.4, MIR2909, AC244093.3, AC244093.5, ACACA, AC244093.1, HMGB1P24, AC244093.2, C17orf78, AC243654.3, TADA2A, AC243654.1, AC243654.2, DUSP14, SYNRG, AC243585.2, DDX52, MIR378J, AC243571.2, AC243585.1, HNF1B, AC243571.1, YWHAEP7, RNU6-489P, TBC1D3K, 5S_rRNA.
- chr17:39,461,486–41,786,931, 152 genes, copy number 8–19 (within-gene range 3–19) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 822. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
